Somatic mutation profile of tumor specimen C3N-02754-01 (aliquot CPT0183850037) from CPTAC case C3N-02754, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 62.0 years (22,651 days).
Specimen C3N-02754-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15113c5f-88f7-4ac6-a523-22df0c64216f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02754-71 (Blood Derived Normal), aliquot CPT0183910002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/283baeea-ab0e-4719-95bf-dde29c1fb9ca

The open-access MAF lists 30 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 6, Nonsense Mutation 2, Intron 2, RNA 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 21/192 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- STK11 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 13/107 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057520017, COSV58821219; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM8 | c.1949C>T p.A650V | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.169); catalogued as rs201827043, COSV69864747; called by muse, mutect2
- DCHS2 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 32/372 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs1202050640; called by muse, mutect2
- FPR1 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754232242, COSV59051992; called by muse, mutect2, varscan2
- SLCO3A1 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 37/361 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.166); catalogued as rs565500840; called by muse, mutect2, varscan2
- SOGA1 | c.4943C>T p.S1648F | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV99412465; called by muse, mutect2, varscan2
- TTN | c.14881G>A p.A4961T (on ENST00000591111; = p.A4034T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/85 reads (12%) | PolyPhen probably damaging (0.998); catalogued as rs754692422, COSV59861214, COSV60157889; called by muse, mutect2
- VEGFB | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 10/118 reads (8%) | catalogued as COSV100374919; called by muse, mutect2
- CCDC168 | c.14191T>A p.S4731T | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- CKAP5 | c.4870-2A>C p.X1624_splice (on ENST00000529230 / NM_001008938.4; = p.X1564_splice on NM_014756.3) | Splice Site (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- CRHBP | c.512C>T p.T171I | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- DOCK7 | c.1492G>A p.V498I | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.387); called by muse, mutect2
- KIAA1109 | c.8510T>C p.V2837A | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2
- MANBAL | c.246G>T p.K82N | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2
- MYO7A | c.4238T>C p.V1413A | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- OTOP1 | c.1214C>G p.S405C | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PTPRQ | c.1793C>T p.P598L (on ENST00000616559; = p.P556L on NM_001145026.2) | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM10 | c.1957A>T p.K653* | Nonsense Mutation (SNP) | VAF 46/192 reads (24%) | called by muse, mutect2, varscan2
- SHC4 | c.1648G>C p.E550Q | Missense Mutation (SNP) | VAF 30/287 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- AJAP1 | c.675G>A p.T225= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs1459076033, COSV65450421; called by muse, varscan2
- CUBN | c.3030G>A p.P1010= | Silent (SNP) | VAF 24/286 reads (8%) | catalogued as rs772693156; called by muse, mutect2
- CYTH4 | c.183G>A p.K61= | Silent (SNP) | VAF 10/148 reads (7%) | catalogued as COSV50633779; called by muse, mutect2
- DOCK2 | c.4596C>T p.N1532= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs372927020; ClinVar: likely benign; called by muse, mutect2
- FRK | c.399A>G p.S133= | Silent (SNP) | VAF 13/163 reads (8%) | called by muse, mutect2
- KRTAP20-2 | c.81T>C p.G27= | Silent (SNP) | VAF 58/546 reads (11%) | catalogued as rs750366154, COSV58183475; called by muse, mutect2, varscan2
- RASGRF1 | c.3542+1587G>A | Intron (SNP) | VAF 6/90 reads (7%) | catalogued as rs921190283; called by muse, mutect2
- RN7SL495P | chr15:22608234 T>C | 3'Flank (SNP) | VAF 36/684 reads (5%) | catalogued as rs768395513; called by muse, mutect2
- SERF2 | c.117-21C>T | Intron (SNP) | VAF 16/153 reads (10%) | catalogued as rs372561860; called by muse, mutect2, varscan2
- SSPOP | n.12837G>A | RNA (SNP) | VAF 9/127 reads (7%) | catalogued as rs751859744; called by muse, mutect2
